Gene-level copy-number profile of tumor specimen HCM-BROD-0115-C16-01A from HCMI case HCM-BROD-0115-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 43.5 years (15,886 days).
Specimen HCM-BROD-0115-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 71dfafbd-55ff-4fcb-9c47-e8b11cc31bb8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0115-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/303d3b40-02ab-4227-bb11-82903140f35f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 11,063; copy number 2: 41,196; copy number 3: 6,615; copy number 4: 2; copy number 5: 13.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr9:9,090,898–9,803,784, 3 genes (within-gene range 0–1): RPS26P3, RN7SL5P, AL513422.1.
- chr14:75,259,411–75,474,111, 7 genes (within-gene range 0–1): AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2, JDP2.
- chr14:106,257,762–106,318,236, 13 genes (within-gene range 0–1): IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:140,865,075–141,456,434, 13 genes, copy number 5: AC121333.1, RPL23AP41, SLC25A36, AC108727.1, SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1.

Autosomal genes at a single copy (total copy number 1): 8,207. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
